Somatic mutation profile of tumor specimen MP2PRT-PAVXZI-TMP1-A (aliquot MP2PRT-PAVXZI-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVXZI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,367 days).
Specimen MP2PRT-PAVXZI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c57d69df-4775-442b-b92b-869622e9f957.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXZI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXZI-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2c6a6b4-1735-4df0-b683-fbaab13608e8

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2770G>A p.G924S | Missense Mutation (SNP) | VAF 107/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587779471, CM000347, CM1412639, COSV58594985; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4198A>T p.S1400C | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54329207, COSV54333702, COSV54341330; called by muse, mutect2, varscan2
- GRM2 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.545); catalogued as rs780930849, COSV99622882; called by muse, mutect2, varscan2
- NMUR2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs768254421, COSV54921636; called by muse, mutect2, varscan2
- VCAN | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371049542; called by muse, mutect2, varscan2
- ANAPC4 | c.1659T>G p.C553W | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ANK2 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CCDC68 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 59/319 reads (18%) | called by muse, mutect2, varscan2
- DMD | c.7768G>A p.E2590K | Missense Mutation (SNP) | VAF 131/322 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F13B | c.632T>G p.L211* | Nonsense Mutation (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2, varscan2
- FGFR2 | c.2385T>A p.D795E | Missense Mutation (SNP) | VAF 93/362 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS7 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 155/393 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- LOXHD1 | c.3738T>G p.H1246Q | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR6B2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- PTPRN | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L1 | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ZMYM1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ANK2 | c.1848G>A p.L616= | Silent (SNP) | VAF 63/244 reads (26%) | catalogued as rs1427576115, COSV52150509; called by muse, mutect2, varscan2
- AXDND1 | c.1668G>A p.G556= | Silent (SNP) | VAF 123/299 reads (41%) | called by muse, mutect2, varscan2
- HELZ2 | c.3213C>T p.D1071= (on ENST00000467148 / NM_001037335.2; = p.D502= on NM_033405.3) | Silent (SNP) | VAF 32/510 reads (6%) | catalogued as rs748700291, COSV100915753; called by muse, mutect2
- IRAK2 | c.1593C>T p.D531= | Silent (SNP) | VAF 126/384 reads (33%) | catalogued as rs200043063; called by muse, mutect2, varscan2
- MYH14 | c.1242C>T p.A414= | Silent (SNP) | VAF 120/324 reads (37%) | called by muse, mutect2, varscan2
- SLC1A3 | c.1167C>T p.F389= | Silent (SNP) | VAF 122/451 reads (27%) | catalogued as rs372548093, COSV54317037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNPO2L | c.405G>A p.E135= | Silent (SNP) | VAF 146/566 reads (26%) | called by muse, mutect2, varscan2
- TBC1D24 | c.696C>T p.F232= | Silent (SNP) | VAF 119/337 reads (35%) | catalogued as COSV53549030; called by muse, mutect2, varscan2
- CTBP2 | c.58+12406C>T | Intron (SNP) | VAF 174/673 reads (26%) | called by muse, mutect2, varscan2
